Somatic mutation profile of tumor specimen 0DVCFH from CCDI case PBCMDS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, metastatic; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 12.3 years (4,480 days).
Specimen 0DVCFH: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdc1f657-1f11-4444-a85b-b6debdcbd820.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/537d6ea8-69ed-41eb-aa46-5bfa9923b7f1

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 6, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 225/500 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PHEX | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 208/479 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65074803; called by muse, mutect2, varscan2
- RTL1 | c.3550C>G p.R1184G | Missense Mutation (SNP) | VAF 126/293 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.288); catalogued as rs755672293, COSV66017206, COSV66017447; called by muse, mutect2, varscan2
- SORCS1 | c.1024+1G>A p.X342_splice | Splice Site (SNP) | VAF 200/425 reads (47%) | catalogued as rs1188351705, COSV99548596; called by muse, mutect2, varscan2
- GLYATL1B | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 115/246 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- IGSF9 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 160/362 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SLITRK4 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 194/483 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADGRV1 | c.3888G>A p.L1296= | Silent (SNP) | VAF 156/356 reads (44%) | catalogued as COSV101316762; called by muse, varscan2
- CC2D2A | c.1185C>T p.I395= | Silent (SNP) | VAF 106/287 reads (37%) | called by muse, mutect2, varscan2
- COL6A5 | c.2319G>A p.E773= | Silent (SNP) | VAF 199/465 reads (43%) | called by muse, mutect2, varscan2
- EP400 | c.3078G>A p.A1026= | Silent (SNP) | VAF 181/387 reads (47%) | catalogued as rs767913284, COSV100201292; called by muse, mutect2, varscan2
- LGALS9C | c.717C>G p.S239= | Silent (SNP) | VAF 198/648 reads (31%) | called by muse, varscan2
- MED27 | c.603C>T p.I201= | Silent (SNP) | VAF 147/331 reads (44%) | catalogued as rs766802903, COSV99406283; called by muse, mutect2, varscan2
- UGT2A3 | c.1032A>T p.T344= | Silent (SNP) | VAF 168/412 reads (41%) | catalogued as rs768534382; called by muse, mutect2, varscan2
- CATSPERG | c.469+82A>T | Intron (SNP) | VAF 52/116 reads (45%) | called by mutect2, varscan2
- TMEM87B | c.1105-1777C>G | Intron (SNP) | VAF 276/314 reads (88%) | called by muse, mutect2, varscan2
